Somatic mutation profile of tumor specimen TARGET-20-PANKFG-09A (aliquot TARGET-20-PANKFG-09A-02D) from TARGET case TARGET-20-PANKFG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (408 days).
Specimen TARGET-20-PANKFG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84e76467-379c-433d-85fb-d6f10bee7997.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANKFG-14A (Bone Marrow Normal), aliquot TARGET-20-PANKFG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/991ceb0a-b09e-4acf-a7ff-c2801f78ed21

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
